Somatic mutation profile of tumor specimen MMRF_2063_1_BM_CD138pos (aliquot MMRF_2063_1_BM_CD138pos_T1_KHS5U_L08146) from MMRF case MMRF_2063, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,615 days).
Specimen MMRF_2063_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea2fb6fa-47b7-4608-90b3-cdecbe0f22c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2063_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2063_1_PB_Whole_C2_KHS5U_L08147; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bcc73d9-96c8-4219-b6ad-d6901f08077b

The open-access MAF lists 107 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 27, Silent 16, Intron 11, 5'UTR 6, Nonsense Mutation 3, 5'Flank 3, 3'Flank 3, RNA 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs11549209, COSV59511395; called by muse, mutect2, varscan2
- AL121899.2 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs374109992, COSV101198632, COSV67351841; called by muse, mutect2, varscan2
- CLEC4M | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144775067; called by muse, mutect2, varscan2
- DGKH | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as rs768426153, COSV54944000; called by muse, mutect2, varscan2
- DHX30 | c.3379C>T p.R1127W (on ENST00000445061 / NM_138615.3; = p.R1088W on NM_014966.3) | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs771169382, COSV53143944; called by muse, mutect2, varscan2
- FLRT3 | c.1660A>G p.R554G | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1413868947; called by muse, mutect2, varscan2
- H2AC17 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1445597091, COSV58152376; called by muse, mutect2, varscan2
- HSPA1L | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 157/529 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs756624684; called by muse, mutect2, varscan2
- IGHG2 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs754780407; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGLV3-1 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs766340911; called by muse, varscan2
- KYAT3 | c.1337_1339del p.I446del | In Frame Del (DEL) | VAF 13/99 reads (13%) | catalogued as rs1159126942; called by pindel, varscan2
- LENG8 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as rs771194664; called by muse, mutect2, varscan2
- PDZD2 | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV56868646; called by muse, mutect2, varscan2
- PKHD1 | c.9868G>T p.D3290Y | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs370659581, COSV100581335; called by muse, mutect2, varscan2
- SASH1 | c.159C>T p.D53= | Splice Region (SNP) | VAF 16/53 reads (30%) | catalogued as rs758083632; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN1A | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1266240114, COSV57684963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK3 | c.4855G>A p.V1619M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99436078; called by muse, mutect2, varscan2
- SLC6A8 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as CD1513021; called by muse, mutect2
- ACAT1 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 144/280 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS10 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMPR2 | c.2856C>G p.S952R | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CBLB | c.2684G>A p.C895Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DDAH1 | c.568T>G p.S190A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF2H3 | c.364_364+4del p.X122_splice | Splice Site (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- HDLBP | c.3794G>A p.G1265D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHG2 | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- IGHV2-70D | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.073); called by muse, varscan2
- IGHV2-70D | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- IGHV3-33 | c.198G>C p.W66C | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- INTS1 | c.1457C>A p.T486N | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NR1H4 | c.1237A>T p.K413* (on ENST00000551379 / NM_001206993.2; = p.K399* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- PRR35 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- PTPRF | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RAPGEF1 | c.649_655del p.S217* | Frame Shift Del (DEL) | VAF 78/125 reads (62%) | called by mutect2, pindel, varscan2
- RRAGC | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TBX5 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZDHHC23 | c.341T>G p.V114G | Missense Mutation (SNP) | VAF 76/124 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZFHX4 | c.3914A>C p.E1305A | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ARC | c.1056C>T p.G352= | Silent (SNP) | VAF 52/97 reads (54%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.720G>C p.S240= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV61528453; called by muse, mutect2, varscan2
- DDX25 | c.1413C>T p.N471= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs760195783; called by muse, mutect2, varscan2
- DNAH2 | c.4356C>T p.Y1452= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- FAT2 | c.6081G>A p.A2027= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as rs192320051, COSV55828781; called by muse, mutect2, varscan2
- GPRASP2 | c.1263C>T p.S421= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as rs752558430; called by muse, varscan2
- IGHV2-70 | c.87G>A p.A29= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs369078954; called by muse, varscan2
- IGHV2-70 | c.28C>T p.L10= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs535109223; called by muse, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as rs1233195687; called by muse, varscan2
- IGLV3-1 | c.306T>A p.A102= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as rs538415293; called by muse, varscan2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as rs376421895; called by muse, mutect2, varscan2
- MED1 | c.693A>G p.L231= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- NOA1 | c.834G>A p.L278= | Silent (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- PDE8B | c.2040C>T p.D680= | Silent (SNP) | VAF 120/185 reads (65%) | called by muse, mutect2, varscan2
- PLXDC2 | c.969C>A p.T323= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- USH2A | c.1059A>T p.S353= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- ABL2 | c.*6493C>A | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26534554 C>T | 5'Flank (SNP) | VAF 16/31 reads (52%) | catalogued as rs938350428; called by muse, mutect2, varscan2
- ACTG1 | c.363+91C>T | Intron (SNP) | VAF 28/47 reads (60%) | catalogued as rs561562719; called by muse, mutect2, varscan2
- ADGRV1 | c.4378+869A>G | Intron (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- ADNP | chr20:50889167 T>A | 3'Flank (SNP) | VAF 18/33 reads (55%) | catalogued as rs1024833478; called by muse, mutect2, varscan2
- AKIRIN2 | c.-471G>T | 5'UTR (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3462C>A | 3'UTR (SNP) | VAF 51/93 reads (55%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*4274T>C | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- ATG7 | c.*2690C>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- ATP10B | c.470+858G>T | Intron (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- BAZ1B | c.-297T>C | 5'UTR (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- BIRC8 | n.1188C>T | RNA (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- BRD9 | c.-29C>A | 5'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2
- CASP2 | c.*459G>T | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CCDC120 | chrX:49068952 T>G | 3'Flank (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- CCNL2 | c.289-95G>C | Intron (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2
- CEP170 | c.*272A>C | 3'UTR (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- CERS5 | c.872+51T>A | Intron (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- CLDN8 | c.*1126A>T | 3'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- CSK | c.-66+5996A>C | Intron (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- CTBP1 | c.195+2198G>A | Intron (SNP) | VAF 61/109 reads (56%) | called by muse, mutect2, varscan2
- CYP26B1 | c.205-83C>T | Intron (SNP) | VAF 70/240 reads (29%) | called by muse, mutect2, varscan2
- ERO1B | c.1343+51A>G | Intron (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- FCRL5 | c.*1572C>G | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- FKTN | c.*1758T>A | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.*9613G>C | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- GRIN2A | c.*8811C>T | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- HHIP | c.*3678G>T | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- ITGAV | c.*42T>A | 3'UTR (SNP) | VAF 83/254 reads (33%) | called by muse, mutect2, varscan2
- LONRF2 | c.*3970G>A | 3'UTR (SNP) | VAF 63/93 reads (68%) | catalogued as rs1024699242; called by muse, mutect2, varscan2
- MAP4K3 | c.*487A>G | 3'UTR (SNP) | VAF 59/87 reads (68%) | called by muse, mutect2, varscan2
- MGAM | c.4618+145C>T | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MTUS2 | c.3118-11194T>C | Intron (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- NTRK2 | c.*32G>A | 3'UTR (SNP) | VAF 219/349 reads (63%) | catalogued as rs372921138, COSV52869004; called by muse, mutect2, varscan2
- PRKCD | c.*74A>G | 3'UTR (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
- SDC1 | c.*1214A>G | 3'UTR (SNP) | VAF 40/149 reads (27%) | catalogued as rs950682697; called by muse, mutect2, varscan2
- SEMA6D | c.*651G>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- SHKBP1 | chr19:40576865 A>T | 5'Flank (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3513C>T | RNA (SNP) | VAF 57/232 reads (25%) | catalogued as rs1369648761; called by muse, mutect2, varscan2
- STK17A | c.*1052dup | 3'UTR (INS) | VAF 7/70 reads (10%) | called by pindel, varscan2
- TFCP2L1 | c.*7555G>T | 3'UTR (SNP) | VAF 13/218 reads (6%) | called by muse, mutect2
- TMTC3 | c.*2498T>C | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- TNRC6B | c.*2655C>T | 3'UTR (SNP) | VAF 18/42 reads (43%) | catalogued as rs1286939982; called by muse, mutect2, varscan2
- USP32 | chr17:60392446 C>A | 5'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- VAV3 | c.*783G>A | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- VGLL4 | c.*682C>G | 3'UTR (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- VPS39 | chr15:42160024 G>C | 3'Flank (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- WBP1 | c.-87G>A | 5'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- XRCC2 | c.*35C>T | 3'UTR (SNP) | VAF 72/264 reads (27%) | catalogued as rs140280051; called by muse, mutect2, varscan2
- ZCCHC12 | c.-4A>T | 5'UTR (SNP) | VAF 96/98 reads (98%) | called by muse, mutect2, varscan2
- ZNF516 | c.*2973A>C | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- ZNF557 | c.-41G>A | 5'UTR (SNP) | VAF 104/171 reads (61%) | catalogued as rs537067067; called by muse, mutect2, varscan2
